Surgical pathology report (de-identified scan), TCGA case TCGA-76-6282, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6282-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-76-6282

FINAL DIAGNOSIS:

1. Left frontal brain tumor: GLIOBLASTOMA MULTIFORM, WHO GRADE IV.
2. Left frontal brain tumor: GLIOBLASTOMA MULTIFORME, WHO GRADE IV.
SEE MICROSCOPIC DESCRIPTION.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Pseudopalisading necrosis and endothelial proliferation are present in the tumor.

Frozen Section Diagnosis:

1. Left frontal brain tumor: Glioblastoma multiforme

Clinical History and Diagnosis:

Left frontal brain tumor

Source of Specimen:

- 1: Left frontal brain tumor
- 2: Left frontal brain tumor

Gross Description:

- [REDACTED]
1. Left frontal brain tumor: A fresh for frozen section and multiple fragments of soft tan and pink tissue measuring in aggregate 1.8 x 1.2 x 0.6 cm. Approximately 75% of the specimen is used for touch preparation and frozen section. The remainder of the specimen

[page 2 of 2]
submitted in one additional cassette.

2. Left frontal brain tumor: Received in formalin, in a specimen container labeled with the patient's name and "#2 left frontal brain tumor", are multiple fragments of tan-pink rubbery tissue measuring 4.5 x 4.5 x 0.6 cm in aggregate. The specimen is sectioned and entirely submitted in 10 cassettes.

Histology Laboratory
H&E

Source: NCI Genomic Data Commons file 2f7ef0f6-43ce-42f2-b5da-8b3b6fe2012c (TCGA-76-6282.FE3B0AEE-6477-48DD-AF17-54F991FA47A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).